Gene-level copy-number profile of tumor specimen TCGA-DM-A1D0-01A from TCGA case TCGA-DM-A1D0, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.1 years (28,875 days).
Specimen TCGA-DM-A1D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e0041807-3f39-4520-8a6a-f90143710166.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A1D0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eca57ef9-0083-467e-8b14-991ed53945f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 8,742; copy number 2: 43,817; copy number 3: 5,655; copy number 4: 81; copy number 5: 1,384; copy number 6: 47; copy number 18: 48; copy number 21: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A1D0-01A-11D-A151-01): tumor purity 0.85, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,500,337–88,584,530, 19 genes (within-gene range 0–1): AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,489 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,988,808–43,674,591, 109 genes, copy number 5 (broad region; genes not listed).
- chr11:63,911,230–64,001,811, 6 genes, copy number 5: RCOR2, NAA40, RNU6-45P, COX8A, AP000721.1, OTUB1.
- chr11:67,711,702–68,130,518, 28 genes, copy number 5: UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4, ALG1L8P, FAM86C2P, ENPP7P7, AP003716.1, LINC02754, RNU6-46P, RPS3AP40, AC004923.1, AC004923.2, AC004923.3, OR7E1P, UNC93B1, ALDH3B1, AC004923.4, NDUFS8, MIR7113, MIR4691, TCIRG1, MIR6753, AP002807.1, CHKA, AP002992.1.
- chr11:77,216,558–79,441,030, 47 genes, copy number 6: GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579.
- chr13:20,777,329–21,295,003, 19 genes, copy number 5 (within-gene range 2–5): XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54, LATS2, LATS2-AS1, RNU4-9P, RPS12P23, IPPKP1, AL161613.1, SNORD27, SAP18, SKA3, MRPL57, AL158032.1, LINC01046, ESRRAP2, AL158032.2.
- chr13:26,222,191–92,873,682, 855 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:93,226,807–94,408,020, 1 gene, copy number 5 (within-gene range 4–5): GPC6.
- chr13:93,818,424–114,337,626, 320 genes, copy number 5 (broad region; genes not listed).
- chr17:34,319,435–34,859,046, 10 genes, copy number 21: CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:39,461,486–41,034,874, 84 genes, copy number 5–18 (within-gene range 1–18) (broad region; genes not listed).
- chr22:30,902,219–30,979,395, 10 genes, copy number 5: EIF4HP2, MORC2-AS1, MORC2, TUG1, AC004542.5, AC004542.4, AC004542.6, AC004542.3, AC004542.2, AC004542.1.

Autosomal genes at a single copy (total copy number 1): 8,742. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
